Somatic mutation profile of tumor specimen TARGET-10-PATPDA-09A (aliquot TARGET-10-PATPDA-09A-01D) from TARGET case TARGET-10-PATPDA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (747 days).
Specimen TARGET-10-PATPDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9aa8396-231b-4881-9728-e3d74fc6157d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATPDA-10A (Blood Derived Normal), aliquot TARGET-10-PATPDA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d89aabb4-897b-4ca6-bd52-c05236a99561

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEXN | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200067011, COSV57361854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSL1 | c.3596G>A p.R1199Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.977); catalogued as rs966487354, COSV54711548; called by muse, mutect2, varscan2
- ADRA1D | c.1170C>T p.L390= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- IRF4 | c.549G>A p.P183= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as rs200431511; called by muse, mutect2, varscan2
- TGM2 | c.1197C>T p.A399= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs777751589, COSV63931222; called by muse, mutect2, varscan2
- RABEPK | c.-146T>A | 5'UTR (SNP) | VAF 14/96 reads (15%) | catalogued as COSV52339045; called by muse, mutect2, varscan2
